Somatic mutation profile of tumor specimen TCGA-J8-A3YH-06A (aliquot TCGA-J8-A3YH-06A-11D-A23M-08) from TCGA case TCGA-J8-A3YH, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 39.6 years (14,470 days).
Specimen TCGA-J8-A3YH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ff497c4-3e2a-406b-9e0d-d37cf907342c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J8-A3YH-10A (Blood Derived Normal), aliquot TCGA-J8-A3YH-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0ebad49-ec31-42cf-93ac-0c6c5d882442

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Frame Shift Del 2, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DOCK8 | c.3700+2T>A p.X1234_splice | Splice Site (SNP) | VAF 37/135 reads (27%) | catalogued as COSV66618388; called by muse, mutect2, varscan2
- KMT2A | c.4001del p.P1334Hfs*22 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, varscan2
- OR11H1 | c.388A>C p.I130L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by mutect2, varscan2
- ZFHX3 | c.4715_4734del p.K1572Rfs*19 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | called by mutect2, pindel
- TMPRSS11F | c.1131C>T p.F377= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV62465225; called by muse, mutect2, varscan2
